Somatic mutation profile of tumor specimen MP2PRT-PAULTZ-TMP1-A (aliquot MP2PRT-PAULTZ-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAULTZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 3.4 years (1,240 days).
Specimen MP2PRT-PAULTZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c79d3616-afea-4c04-b47f-8141b1053ece.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAULTZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAULTZ-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc7347de-cfd8-412b-af0f-38ccccb91de6

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, In Frame Ins 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX27 | c.1648C>T p.R550W | Missense Mutation (SNP) | VAF 12/305 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1194271756, COSV65604983; called by muse, mutect2
- NR3C2 | c.2840G>A p.R947Q | Missense Mutation (SNP) | VAF 115/247 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV60991062; called by muse, mutect2, varscan2
- RGS3 | c.2546C>T p.A849V (on ENST00000350696 / NM_001282923.2; = p.A568V on NM_130795.4) | Missense Mutation (SNP) | VAF 176/392 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs1168147157; called by muse, mutect2, varscan2
- SVIL | c.3040G>A p.E1014K (on ENST00000355867 / NM_021738.3; = p.E588K on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/326 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.26); catalogued as COSV63442938; called by muse, mutect2
- CRAMP1 | c.3038G>A p.G1013D | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2
- DMD | c.655G>T p.D219Y | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FLNB | c.67_68insGCC p.T23delinsSP | In Frame Ins (INS) | VAF 152/328 reads (46%) | called by mutect2, pindel*, varscan2*
- NDNF | c.1415C>G p.T472S | Missense Mutation (SNP) | VAF 99/211 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- PICK1 | c.337T>C p.S113P | Missense Mutation (SNP) | VAF 96/216 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- PRR36 | c.3745C>G p.L1249V | Missense Mutation (SNP) | VAF 64/590 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PRR36 | c.1042C>T p.Q348* | Nonsense Mutation (SNP) | VAF 53/546 reads (10%) | called by muse, mutect2
- PSMC5 | c.115A>T p.S39C | Missense Mutation (SNP) | VAF 92/195 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- TSEN2 | c.733C>A p.L245I | Missense Mutation (SNP) | VAF 19/408 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.076); called by muse, mutect2
- PRR36 | c.2109C>G p.L703= | Silent (SNP) | VAF 43/496 reads (9%) | catalogued as rs1350586748; called by muse, mutect2
- RIMS2 | c.4053C>T p.L1351= | Silent (SNP) | VAF 10/156 reads (6%) | catalogued as rs1402320014; called by muse, mutect2
- ZPBP2 | c.861T>A p.R287= (on ENST00000348931 / NM_199321.3; = p.R265= on NM_198844.3) | Silent (SNP) | VAF 9/205 reads (4%) | called by muse, mutect2
- FAM131A | chr3:184338431 C>T | 5'Flank (SNP) | VAF 144/296 reads (49%) | called by muse, mutect2, varscan2
